Somatic mutation profile of tumor specimen BA3087D (aliquot aq-BA3087D) from BEATAML1.0 case 2693, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 31.6 years (11,530 days).
Specimen BA3087D: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ea4e036e-4593-48f1-948e-797c060caa1e.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA3444D (Solid Tissue Normal), aliquot aq-BA3444D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/119e504c-5be2-4386-ae23-66fe6156340f

The open-access MAF lists 3 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 2, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SCNN1A | c.930C>G p.D310E | Missense Mutation (SNP) | VAF 32/295 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.011); called by muse, varscan2
- ZFP42 | c.272T>G p.L91R | Missense Mutation (SNP) | VAF 51/464 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- SNED1 | c.108C>T p.A36= | Silent (SNP) | VAF 5/65 reads (8%) | called by muse, mutect2
